Somatic mutation profile of tumor specimen HCM-CSHL-0507-C20-06A (aliquot HCM-CSHL-0507-C20-06A-11D-A82H-36) from HCMI case HCM-CSHL-0507-C20, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectum, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: GX; Age at diagnosis: 61.5 years (22,461 days).
Specimen HCM-CSHL-0507-C20-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ca4b5873-e987-4e42-ad7b-b0360c5ca4c1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0507-C20-11A (Solid Tissue Normal), aliquot HCM-CSHL-0507-C20-11A-01D-A82H-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/40a3b1b0-5037-4a21-bf9a-644efaaa6ff0

The open-access MAF lists 111 somatic variants for this specimen: 81 protein-altering or splice-affecting, 29 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 64, Silent 29, Nonsense Mutation 9, Frame Shift Del 4, Frame Shift Ins 2, Intron 1, Splice Site 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.4666dup p.T1556Nfs*3 | Frame Shift Ins (INS) | VAF 89/264 reads (34%) | catalogued as rs587783031, COSV57351096; ClinVar: uncertain significance / pathogenic; called by mutect2, pindel, varscan2
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 119/303 reads (39%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.745A>T p.R249W | Missense Mutation (SNP) | VAF 177/199 reads (89%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen possibly damaging (0.838); catalogued as rs587782082, COSV52662247, COSV52676356, COSV52892337, COSV52908430; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- TTN | c.47098C>T p.R15700* (on ENST00000591111; = p.R8276* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 109/250 reads (44%) | catalogued as rs926741242, COSV59911426, COSV60201743; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ALDH16A1 | c.775C>T p.R259* | Nonsense Mutation (SNP) | VAF 170/359 reads (47%) | catalogued as rs758312798; called by muse, mutect2, varscan2
- APC | c.2287G>T p.E763* | Nonsense Mutation (SNP) | VAF 94/202 reads (47%) | catalogued as CM106354, COSV57350231; called by muse, varscan2
- APC | c.3080A>G p.Y1027C | Missense Mutation (SNP) | VAF 72/175 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs869312784, COSV57396420; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CLCN2 | c.932G>A p.R311Q | Missense Mutation (SNP) | VAF 93/358 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.188); catalogued as rs1382714741; called by muse, mutect2, varscan2
- CRHR1 | c.254G>A p.R85Q | Missense Mutation (SNP) | VAF 108/271 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs766278959, COSV53276701; called by muse, mutect2, varscan2
- DAPK1 | c.298G>C p.E100Q | Missense Mutation (SNP) | VAF 12/289 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1362592392; called by muse, mutect2
- DIS3L2 | c.2575C>T p.R859W | Missense Mutation (SNP) | VAF 91/417 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.634); catalogued as rs756617073, COSV56059243; called by muse, mutect2, varscan2
- DOCK3 | c.2633G>T p.G878V | Missense Mutation (SNP) | VAF 16/288 reads (6%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.76); catalogued as COSV56540002; called by muse, mutect2
- EMID1 | c.1142G>A p.R381H | Missense Mutation (SNP) | VAF 97/269 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.463); catalogued as rs764653508; called by muse, mutect2, varscan2
- EPHA5 | c.805G>A p.D269N | Missense Mutation (SNP) | VAF 129/275 reads (47%) | SIFT tolerated (0.3); PolyPhen benign (0.076); catalogued as rs773032839, COSV56634701; called by muse, mutect2, varscan2
- FLG | c.2338C>T p.R780C | Missense Mutation (SNP) | VAF 24/450 reads (5%) | SIFT tolerated (0.14); PolyPhen benign (0.042); catalogued as rs753102917, COSV64242581; called by muse, mutect2
- FZR1 | c.1211A>G p.N404S | Missense Mutation (SNP) | VAF 95/376 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.383); catalogued as rs1357788894; called by muse, mutect2, varscan2
- KEL | c.2147G>A p.R716H | Missense Mutation (SNP) | VAF 213/487 reads (44%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs765595801, COSV100786964; called by muse, varscan2
- KIAA1755 | c.2990G>A p.R997H | Missense Mutation (SNP) | VAF 114/907 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.052); catalogued as rs747051689, COSV54073295; called by muse, mutect2, varscan2
- MMP16 | c.1801C>T p.R601C | Missense Mutation (SNP) | VAF 108/246 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1271222004, COSV54165455; called by muse, mutect2, varscan2
- MNDA | c.1177-1G>A p.X393_splice | Splice Site (SNP) | VAF 26/130 reads (20%) | catalogued as COSV63739783; called by muse, mutect2
- NEO1 | c.3352G>A p.V1118M | Missense Mutation (SNP) | VAF 165/190 reads (87%) | SIFT deleterious (0); PolyPhen possibly damaging (0.674); catalogued as rs746965566, COSV56073893; called by muse, mutect2, varscan2
- NGFR | c.433G>A p.V145M | Missense Mutation (SNP) | VAF 166/706 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.257); catalogued as rs770527312; called by muse, mutect2, varscan2
- NLRP1 | c.4279C>T p.R1427W (on ENST00000572272 / NM_033004.4; = p.R1383W on NM_014922.5) | Missense Mutation (SNP) | VAF 112/224 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs754014640, COSV52566950, COSV99335467; called by muse, mutect2, varscan2
- NLRP1 | c.85G>A p.A29T | Missense Mutation (SNP) | VAF 206/232 reads (89%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as rs971095282; called by muse, mutect2, varscan2
- NOMO1 | c.1843G>A p.G615R | Missense Mutation (SNP) | VAF 92/307 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1405138543; called by muse, mutect2, varscan2
- NRBP2 | c.1064C>T p.P355L | Missense Mutation (SNP) | VAF 209/472 reads (44%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs539183961, COSV59918256; called by muse, mutect2, varscan2
- NTNG2 | c.548G>A p.R183H | Missense Mutation (SNP) | VAF 141/557 reads (25%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.842); catalogued as rs759223913; called by muse, mutect2, varscan2
- NTSR2 | c.560C>T p.P187L | Missense Mutation (SNP) | VAF 21/661 reads (3%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as rs1477323957; called by muse, mutect2
- NUP93 | c.980G>A p.R327H | Missense Mutation (SNP) | VAF 138/338 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs771130377, COSV57428419; called by muse, mutect2, varscan2
- OBSL1 | c.4241G>A p.R1414H | Missense Mutation (SNP) | VAF 244/575 reads (42%) | SIFT tolerated (0.81); PolyPhen benign (0.01); catalogued as rs762539444; called by muse, mutect2, varscan2
- OR5I1 | c.652A>G p.I218V | Missense Mutation (SNP) | VAF 67/233 reads (29%) | SIFT tolerated (0.53); PolyPhen benign (0.003); catalogued as rs1332420849; called by muse, mutect2, varscan2
- PKLR | c.1433G>C p.G478A | Missense Mutation (SNP) | VAF 66/292 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); catalogued as COSV61360645; called by muse, mutect2, varscan2
- PLXNA2 | c.1576C>T p.P526S | Missense Mutation (SNP) | VAF 127/274 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs1391420340; called by muse, mutect2, varscan2
- POU4F3 | c.331G>A p.V111M | Missense Mutation (SNP) | VAF 276/627 reads (44%) | SIFT tolerated (0.23); PolyPhen benign (0.006); catalogued as COSV57942353; called by muse, mutect2, varscan2
- PPP6R1 | c.2428G>A p.G810R | Missense Mutation (SNP) | VAF 169/338 reads (50%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.001); catalogued as rs767658439, COSV58984111; called by muse, varscan2
- PRLH | c.98G>A p.R33H | Missense Mutation (SNP) | VAF 142/337 reads (42%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as rs766168277; called by muse, mutect2, varscan2
- PROKR2 | c.226G>A p.A76T | Missense Mutation (SNP) | VAF 182/397 reads (46%) | SIFT tolerated (0.21); PolyPhen benign (0.013); catalogued as rs776908572, COSV54087946; called by muse, mutect2, varscan2
- PTBP2 | c.40A>C p.T14P (on ENST00000426398 / NM_001300986.2; = p.T6P on NM_021190.4) | Missense Mutation (SNP) | VAF 63/252 reads (25%) | SIFT tolerated, low confidence (0.31); PolyPhen probably damaging (0.986); catalogued as rs1319096977; called by muse, mutect2, varscan2
- RGSL1 | c.3052G>A p.A1018T | Missense Mutation (SNP) | VAF 129/288 reads (45%) | SIFT tolerated (0.47); PolyPhen benign (0.005); catalogued as rs1365640438; called by muse, mutect2, varscan2
- RYR2 | c.3461G>A p.R1154H | Missense Mutation (SNP) | VAF 141/331 reads (43%) | SIFT tolerated (0.09); PolyPhen benign (0.061); catalogued as rs530867686, COSV63713805; called by muse, mutect2, varscan2
- SLITRK5 | c.2785C>T p.R929W | Missense Mutation (SNP) | VAF 140/1004 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV61522531; called by muse, varscan2
- SPACA9 | c.385G>A p.E129K | Missense Mutation (SNP) | VAF 163/378 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs755256506, COSV100051376; called by muse, mutect2, varscan2
- THBS4 | c.2759G>T p.R920L | Missense Mutation (SNP) | VAF 100/459 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63467655; called by muse, mutect2, varscan2
- TSPAN7 | c.548C>T p.P183L | Missense Mutation (SNP) | VAF 253/274 reads (92%) | SIFT tolerated (0.08); PolyPhen benign (0.026); catalogued as rs776814898; called by muse, mutect2, varscan2
- UBASH3B | c.458G>A p.R153H | Missense Mutation (SNP) | VAF 214/363 reads (59%) | SIFT deleterious (0.03); PolyPhen benign (0.022); catalogued as rs756434598, COSV52495623; called by muse, mutect2, varscan2
- WDR83OS | c.80C>T p.P27L | Missense Mutation (SNP) | VAF 168/413 reads (41%) | SIFT tolerated (0.08); PolyPhen benign (0.084); catalogued as rs780185655, COSV99663915; called by muse, mutect2, varscan2
- ZNF723 | c.788G>A p.G263D | Missense Mutation (SNP) | VAF 40/137 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs554906814; called by muse, mutect2, varscan2
- AC021072.1 | c.234C>A p.C78* | Nonsense Mutation (SNP) | VAF 117/531 reads (22%) | called by muse, mutect2, varscan2
- AKR1B15 | c.454C>A p.P152T | Missense Mutation (SNP) | VAF 87/229 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- ANLN | c.1388C>T p.T463I | Missense Mutation (SNP) | VAF 96/218 reads (44%) | SIFT tolerated (0.12); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ARHGAP45 | c.1575G>C p.Q525H | Missense Mutation (SNP) | VAF 217/454 reads (48%) | SIFT tolerated (0.1); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- C4orf50 | c.199G>T p.A67S | Missense Mutation (SNP) | VAF 74/368 reads (20%) | SIFT tolerated (0.91); PolyPhen possibly damaging (0.475); called by muse, varscan2
- CLIP4 | c.972del p.N324Kfs*26 | Frame Shift Del (DEL) | VAF 128/345 reads (37%) | called by mutect2, pindel, varscan2
- CNTN3 | c.451G>T p.G151* | Nonsense Mutation (SNP) | VAF 12/230 reads (5%) | called by muse, mutect2
- DOCK2 | c.1677G>T p.M559I | Missense Mutation (SNP) | VAF 24/298 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.294); called by muse, mutect2
- EBF1 | c.1595C>T p.S532F | Missense Mutation (SNP) | VAF 172/357 reads (48%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.519); called by muse, mutect2, varscan2
- EFNB2 | c.390dup p.D131Rfs*17 | Frame Shift Ins (INS) | VAF 52/452 reads (12%) | called by mutect2, pindel, varscan2
- FBXO11 | c.220G>A p.V74I | Missense Mutation (SNP) | VAF 232/489 reads (47%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.029); called by muse, varscan2
- FLG | c.7399G>A p.G2467R | Missense Mutation (SNP) | VAF 134/333 reads (40%) | SIFT tolerated (0.11); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- GATA6 | c.1770C>A p.C590* | Nonsense Mutation (SNP) | VAF 71/172 reads (41%) | called by muse, mutect2, varscan2
- GPN2 | c.413_419del p.L138Pfs*86 | Frame Shift Del (DEL) | VAF 75/193 reads (39%) | called by mutect2, pindel, varscan2
- MDC1 | c.5261G>T p.R1754M | Missense Mutation (SNP) | VAF 297/627 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.894); called by muse, mutect2, varscan2
- MYBPH | c.55T>C p.S19P | Missense Mutation (SNP) | VAF 184/469 reads (39%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); called by muse, mutect2, varscan2
- MYCBP2 | c.1483A>C p.I495L (on ENST00000357337; = p.I533L on NM_015057.5) | Missense Mutation (SNP) | VAF 49/854 reads (6%) | SIFT tolerated (0.53); PolyPhen benign (0); called by muse, mutect2
- N6AMT1 | c.626T>C p.L209P | Missense Mutation (SNP) | VAF 58/218 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, varscan2
- NBPF14 | c.4621T>C p.Y1541H | Missense Mutation (SNP) | VAF 129/386 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.934); called by muse, mutect2
- OSBPL6 | c.976del p.I326Yfs*55 | Frame Shift Del (DEL) | VAF 98/222 reads (44%) | called by mutect2, pindel, varscan2
- PTEN | c.733_744del p.Q245_P248del | In Frame Del (DEL) | VAF 68/98 reads (69%) | called by mutect2, pindel, varscan2
- RAD51B | c.1000G>A p.V334I | Missense Mutation (SNP) | VAF 42/151 reads (28%) | SIFT tolerated (0.41); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- RALGDS | c.628G>T p.E210* | Nonsense Mutation (SNP) | VAF 95/405 reads (23%) | called by muse, mutect2, varscan2
- SLC26A3 | c.412G>T p.G138* | Nonsense Mutation (SNP) | VAF 72/314 reads (23%) | called by muse, mutect2, varscan2
- SLC7A6OS | c.870C>A p.Y290* | Nonsense Mutation (SNP) | VAF 86/389 reads (22%) | called by muse, mutect2, varscan2
- TDRD6 | c.2453G>T p.R818I | Missense Mutation (SNP) | VAF 66/331 reads (20%) | SIFT deleterious (0.05); PolyPhen benign (0.068); called by muse, mutect2, varscan2
- TMEM248 | c.738_739del p.Y247Sfs*14 | Frame Shift Del (DEL) | VAF 101/328 reads (31%) | called by pindel, varscan2
- TRO | c.2327G>T p.S776I | Missense Mutation (SNP) | VAF 94/230 reads (41%) | SIFT tolerated (0.08); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- UACA | c.3364A>G p.K1122E | Missense Mutation (SNP) | VAF 133/150 reads (89%) | SIFT tolerated (0.27); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- UCKL1 | c.1297C>A p.P433T | Missense Mutation (SNP) | VAF 70/517 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- UNC13C | c.1351G>A p.D451N | Missense Mutation (SNP) | VAF 134/158 reads (85%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- WNK1 | c.1267T>A p.S423T | Missense Mutation (SNP) | VAF 28/374 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.617); called by muse, mutect2
- XPNPEP2 | c.377A>G p.D126G | Missense Mutation (SNP) | VAF 10/229 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); called by muse, mutect2
- ZNF471 | c.53A>T p.D18V | Missense Mutation (SNP) | VAF 60/147 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ANKRD30A | c.1650G>T p.P550= (on ENST00000611781; = p.P494= on NM_052997.2) | Silent (SNP) | VAF 29/76 reads (38%) | called by muse, mutect2, varscan2
- CA11 | c.420C>T p.R140= | Silent (SNP) | VAF 130/299 reads (43%) | called by muse, mutect2, varscan2
- CEACAM5 | c.567C>G p.P189= | Silent (SNP) | VAF 97/418 reads (23%) | called by muse, mutect2, varscan2
- CSMD1 | c.6831C>T p.F2277= (on ENST00000520002; = p.F2276= on NM_033225.6) | Silent (SNP) | VAF 81/215 reads (38%) | catalogued as rs371661443, COSV59378788; called by muse, mutect2, varscan2
- CSMD1 | c.2982C>T p.S994= (on ENST00000520002; = p.S993= on NM_033225.6) | Silent (SNP) | VAF 173/369 reads (47%) | catalogued as rs372606827; called by muse, varscan2
- DZANK1 | c.2184C>G p.L728= (on ENST00000262547 / NM_001099407.1; = p.L535= on NM_018152.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 98/431 reads (23%) | catalogued as rs761245722, COSV52757429; called by muse, mutect2, varscan2
- ELL3 | c.628C>A p.R210= | Silent (SNP) | VAF 26/194 reads (13%) | catalogued as rs144962107; called by muse, mutect2, varscan2
- ETNK1 | c.351A>G p.L117= | Silent (SNP) | VAF 151/317 reads (48%) | catalogued as rs753384841, COSV56883592; called by muse, mutect2, varscan2
- FAT2 | c.9033T>C p.C3011= | Silent (SNP) | VAF 92/228 reads (40%) | catalogued as COSV99944440; called by mutect2, varscan2
- GALNT9 | c.507C>T p.R169= | Silent (SNP) | VAF 217/455 reads (48%) | catalogued as rs1555239877; called by muse, mutect2, varscan2
- GIT1 | c.1878A>G p.P626= | Silent (SNP) | VAF 80/409 reads (20%) | called by muse, mutect2, varscan2
- GNAS | c.1503C>T p.A501= | Silent (SNP) | VAF 969/1313 reads (74%) | catalogued as rs1256423726; called by muse, mutect2, varscan2
- HEATR3 | c.51G>A p.T17= | Silent (SNP) | VAF 50/697 reads (7%) | catalogued as rs751476885; called by muse, mutect2
- IRX4 | c.873C>T p.A291= | Silent (SNP) | VAF 180/766 reads (23%) | catalogued as rs1182368536; called by muse, mutect2, varscan2
- KRTAP27-1 | c.453C>T p.F151= | Silent (SNP) | VAF 98/391 reads (25%) | catalogued as rs781274963, COSV67000922; called by muse, mutect2, varscan2
- MN1 | c.3372G>A p.P1124= | Silent (SNP) | VAF 265/649 reads (41%) | catalogued as rs766570466, COSV56559133; called by muse, mutect2, varscan2
- NXPH2 | c.720T>C p.V240= | Silent (SNP) | VAF 60/314 reads (19%) | called by muse, mutect2, varscan2
- PHF11 | c.783C>T p.I261= | Silent (SNP) | VAF 71/567 reads (13%) | catalogued as rs746222741; called by muse, mutect2, varscan2
- PHF21B | c.111C>T p.S37= | Silent (SNP) | VAF 146/345 reads (42%) | called by muse, mutect2, varscan2
- PTPN13 | c.1204C>A p.R402= | Silent (SNP) | VAF 34/119 reads (29%) | catalogued as COSV57404584; called by muse, mutect2, varscan2
- QSOX2 | c.729C>T p.D243= | Silent (SNP) | VAF 190/402 reads (47%) | catalogued as rs572941682, COSV62393916; called by muse, mutect2, varscan2
- RCOR1 | c.1014G>A p.L338= | Silent (SNP) | VAF 59/143 reads (41%) | catalogued as COSV99217777; called by muse, mutect2, varscan2
- SMG1 | c.5814C>G p.S1938= | Silent (SNP) | VAF 61/292 reads (21%) | called by muse, mutect2, varscan2
- STIL | c.1965A>G p.A655= | Silent (SNP) | VAF 83/354 reads (23%) | called by muse, mutect2, varscan2
- TOP2B | c.4419T>A p.S1473= (on ENST00000264331 / NM_001330700.2; = p.S1468= on NM_001068.3) | Silent (SNP) | VAF 10/158 reads (6%) | called by muse, mutect2
- TOPAZ1 | c.2715C>T p.D905= | Silent (SNP) | VAF 55/194 reads (28%) | called by muse, mutect2, varscan2
- VANGL2 | c.969T>C p.S323= | Silent (SNP) | VAF 146/320 reads (46%) | called by muse, mutect2, varscan2
- XKR6 | c.1212C>T p.G404= | Silent (SNP) | VAF 163/392 reads (42%) | catalogued as rs139763869, COSV58654723; called by muse, mutect2, varscan2
- ZNF446 | c.720G>A p.P240= | Silent (SNP) | VAF 179/406 reads (44%) | catalogued as rs767849151, COSV59992221; called by muse, mutect2, varscan2
- CSMD2 | c.8312-7398G>A | Intron (SNP) | VAF 119/336 reads (35%) | catalogued as rs765912423; called by muse, mutect2, varscan2
